Somatic mutation profile of tumor specimen TCGA-91-8496-01A (aliquot TCGA-91-8496-01A-11D-2393-08) from TCGA case TCGA-91-8496, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.0 years (23,358 days).
Specimen TCGA-91-8496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a508d3c7-72da-4149-84a0-292da3558fb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-8496-10A (Blood Derived Normal), aliquot TCGA-91-8496-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/715bb9b5-0819-4e8e-9efe-f38e24d9f142

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIGN | c.1258del p.L420Ffs*5 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs1555685797, COSV100716193; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGO4 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV100943052, COSV64617073; called by muse, mutect2, varscan2
- ANKMY2 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100187299, COSV61012436; called by muse, mutect2
- CHIT1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99705547; called by muse, mutect2, varscan2
- EFR3A | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99603502; called by muse, mutect2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 30/128 reads (23%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- GABBR2 | c.2458C>A p.P820T | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99411231; called by muse, mutect2, varscan2
- KIAA0408 | c.1430C>G p.T477S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV100847039; called by muse, mutect2, varscan2
- KSR1 | c.2215C>T p.R739* (on ENST00000644974 / NM_001367810.1; = p.R624* on NM_014238.2) | Nonsense Mutation (SNP) | VAF 38/193 reads (20%) | catalogued as COSV99260589; called by muse, mutect2, varscan2
- MAML2 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV101594177; called by muse, mutect2
- NAPEPLD | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as rs779238523, COSV100440007; called by muse, mutect2, varscan2
- OR2L2 | c.200T>A p.L67H | Missense Mutation (SNP) | VAF 40/564 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100824296; called by muse, mutect2
- PCDHA1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554117407, COSV65375967; called by muse, mutect2, varscan2
- SLC38A3 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs587742060, COSV101309985; called by muse, mutect2, varscan2
- SOGA3 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 74/322 reads (23%) | catalogued as COSV100847040; called by muse, mutect2, varscan2
- SRRM2 | c.5153C>G p.S1718C | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100071355; called by muse, mutect2
- STON1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs144911860, COSV59132866; called by muse, mutect2
- TMEM259 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312829; called by muse, mutect2, varscan2
- ZNF318 | c.2134T>C p.F712L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.872); catalogued as COSV100546458; called by muse, mutect2, varscan2
- DLC1 | c.2481dup p.S828Lfs*6 (on ENST00000276297 / NM_001348081.2; = p.S391Lfs*6 on NM_006094.5) | Frame Shift Ins (INS) | VAF 37/182 reads (20%) | called by mutect2, pindel, varscan2
- PPP3CA | c.717del p.F239Lfs*64 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- ZNF488 | c.321G>C p.R107S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.157); called by muse, mutect2
- ANO2 | c.531C>T p.S177= (on ENST00000356134 / NM_001278597.3; = p.S181= on NM_001278596.3) | Silent (SNP) | VAF 67/267 reads (25%) | catalogued as rs1310518482, COSV100502032; called by muse, mutect2, varscan2
- EHHADH | c.771A>T p.L257= | Silent (SNP) | VAF 71/274 reads (26%) | catalogued as COSV99213337; called by muse, mutect2, varscan2
- KLHL17 | c.1764C>T p.S588= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV100647591; called by muse, mutect2, varscan2
- LRRK1 | c.5172C>T p.C1724= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV99438873; called by muse, mutect2, varscan2
- MCL1 | c.342G>T p.P114= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100329716; called by muse, mutect2, varscan2
- MYH7 | c.2058C>T p.N686= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100806509, COSV100806760; called by muse, mutect2, varscan2
- POLE | c.1725G>A p.E575= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV100267961; called by muse, mutect2, varscan2
- RPS6KA3 | c.252A>G p.L84= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV101084624; called by muse, mutect2
- SSPOP | n.7170G>T | RNA (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100022898, COSV50487604; called by muse, mutect2
